TARGET case TARGET-30-PASZFX — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Heart, mediastinum, and pleura. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8dad120b-1b15-572d-b5b2-5903d34fd5d4

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 4 years; Vital status: Dead; Days to death: 2,828 days (7.7 years).

Diagnoses (1)
1. Ganglioneuroblastoma: ICD-O-3 morphology code: 9490/3; ICD-10 code: C38.2; Tissue or organ of origin: Posterior mediastinum; Classification of tumor: primary; Age at diagnosis: 4.6 years (1,662 days); Year of diagnosis: 2009; Days to last follow up: 2,828 days (7.7 years); Cog neuroblastoma risk group: Low Risk; INSS stage: Stage 2A.
   Pathology details: Percent tumor nuclei: 90.
   Treatment given: Protocol identifier: ANBL00B1.

Follow-up (1 entry)
- Days to follow up: 2,828 days (7.7 years); Days to first event: 2,828 days (7.7 years); First event: Event; Year of follow up: 2017.

Molecular and laboratory tests
- MYCN amplification: Not Amplified.
- Test: Normal; Ploidy: Diploid.

Biospecimens (2 samples)
- Sample TARGET-30-PASZFX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample TARGET-30-PASZFX-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_NBL_ClinicalData_Validation_20230322.xlsx (sheet Clinical Data):
- First Event: Event
- Overall Survival Time in Days: 2828
- Ploidy: Diploid (DI=1)
- Ploidy Value: 1
- Histology: Favorable
- Diagnostic Category: Ganglioneuroblastoma, intermixed
